Somatic mutation profile of tumor specimen TCGA-5P-A9KE-01A (aliquot TCGA-5P-A9KE-01A-11D-A42J-10) from TCGA case TCGA-5P-A9KE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 70.7 years (25,805 days).
Specimen TCGA-5P-A9KE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2fcdfa0-df07-4acc-afbd-8b368a8a78d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9KE-10A (Blood Derived Normal), aliquot TCGA-5P-A9KE-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc8a3b20-843e-4e1f-a7eb-599d96c05008

The open-access MAF lists 94 somatic variants for this specimen: 70 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 22, Frame Shift Del 5, Frame Shift Ins 3, Nonsense Mutation 2, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.2899T>C p.W967R | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs368716488; called by muse, mutect2, varscan2
- AC131160.1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); catalogued as COSV100226404; called by muse, mutect2
- AGAP3 | c.2175G>T p.K725N (on ENST00000622464; = p.K761N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101257470; called by muse, mutect2, varscan2
- ALDH6A1 | c.1487A>T p.N496I | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100620979; called by muse, mutect2, varscan2
- ATXN7L2 | c.2158A>G p.K720E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100149970; called by muse, mutect2, varscan2
- BMPR1A | c.912G>C p.Q304H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100923723; called by muse, mutect2, varscan2
- C1orf74 | c.488A>G p.H163R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99163057; called by muse, mutect2, varscan2
- CACNA1D | c.6218G>A p.R2073H (on ENST00000350061 / NM_001128840.3; = p.R2093H on NM_000720.4) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as rs745397912, COSV99860377; called by muse, mutect2, varscan2
- CALCRL | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs374525357; called by muse, mutect2
- CCT3 | c.1609G>C p.G537R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV99827559; called by muse, mutect2, varscan2
- CDH9 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV50418001, COSV99160814; called by muse, mutect2, varscan2
- CEP120 | c.2231G>A p.R744H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376401743, COSV100071542; called by muse, mutect2, varscan2
- COL16A1 | c.4733G>C p.C1578S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99595651; called by muse, mutect2, varscan2
- COPS6 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100385215; called by muse, mutect2, varscan2
- CTNNB1 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100846545; called by muse, mutect2, varscan2
- DCC | c.458T>G p.M153R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100503466; called by muse, mutect2, varscan2
- DDX18 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99604875; called by muse, mutect2, varscan2
- DNAH7 | c.9772C>A p.L3258I | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV100416313, COSV100418060; called by muse, mutect2, varscan2
- DNAJC30 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99736992; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99143779; called by muse, mutect2, varscan2
- EFCAB5 | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV100300895; called by muse, mutect2
- EFCAB5 | c.1447A>T p.K483* | Nonsense Mutation (SNP) | VAF 28/166 reads (17%) | catalogued as COSV100300899; called by muse, mutect2
- EIF2AK4 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99775487; called by muse, mutect2, varscan2
- EPB42 | c.1677C>A p.N559K (on ENST00000441366 / NM_001114134.2; = p.N589K on NM_000119.3) | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100282199; called by muse, mutect2, varscan2
- GCLM | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.136); catalogued as COSV100934031; called by muse, mutect2, varscan2
- GPRC6A | c.1517A>T p.Q506L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100114871; called by muse, mutect2, varscan2
- HIP1R | c.1032dup p.N345Qfs*13 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs1442863063; called by mutect2, pindel, varscan2
- IL17RA | c.1926A>C p.E642D | Missense Mutation (SNP) | VAF 99/395 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.393); catalogued as COSV100083498; called by muse, mutect2, varscan2
- ITM2C | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100419677, COSV58398584; called by muse, mutect2, varscan2
- KEAP1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KRT73 | c.379A>C p.K127Q | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV99988911; called by muse, mutect2, varscan2
- LRRC57 | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV99535578; called by muse, mutect2, varscan2
- MICAL2 | c.2544A>T p.E848D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99818508; called by muse, mutect2, varscan2
- MICAL3 | c.4934G>A p.R1645H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs369106641; called by muse, mutect2, varscan2
- MINK1 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100767312; called by muse, mutect2, varscan2
- MN1 | c.2576A>T p.K859I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100180207; called by muse, mutect2, varscan2
- MON2 | c.521C>G p.T174S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99743347, COSV99743870; called by muse, mutect2, varscan2
- NPM1 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.481); catalogued as COSV99744832; called by muse, mutect2, varscan2
- OR5H6 | c.842C>T p.P281L (on ENST00000642105; = p.P265L on NM_001005479.2) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs200721570, COSV67350961; called by muse, mutect2, varscan2
- PHLDB1 | c.1031G>C p.R344P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100616847, COSV61880262; called by muse, mutect2, varscan2
- PPIL2 | c.53A>T p.Y18F | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100622745; called by muse, mutect2
- RNF17 | c.1489A>G p.R497G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99694634; called by muse, mutect2, varscan2
- RNFT2 | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99732514; called by muse, mutect2, varscan2
- RPL10A | c.311-2A>G p.X104_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100003637; called by muse, mutect2, varscan2
- RYR3 | c.3995T>A p.I1332N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV101214954; called by muse, mutect2, varscan2
- SACS | c.1346C>G p.P449R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101207791; called by muse, mutect2, varscan2
- SAYSD1 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1165417354, COSV100010283; called by muse, mutect2, varscan2
- SEC13 | c.664C>T p.P222S (on ENST00000350697 / NM_183352.3; = p.P225S on NM_030673.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771897317, COSV100491479; called by muse, mutect2, varscan2
- SETD9 | c.172A>C p.K58Q | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99605754; called by muse, mutect2, varscan2
- SHMT1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.936); catalogued as rs140862126; called by muse, mutect2, varscan2
- SLC2A4 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs768365925, COSV50300355; called by muse, mutect2, varscan2
- SMYD1 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.297); catalogued as COSV101352542; called by muse, mutect2, varscan2
- SPTA1 | c.3461G>C p.G1154A | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV100935698; called by muse, mutect2, varscan2
- STAT3 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV99233351; called by muse, mutect2, varscan2
- STOX1 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100058310; called by muse, mutect2, varscan2
- TASOR | c.1249T>G p.L417V (on ENST00000355628 / NM_001365636.2; = p.L21V on NM_015224.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100843713; called by muse, mutect2, varscan2
- TNFRSF11A | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV54025746, COSV99500672; called by muse, mutect2, varscan2
- USH2A | c.376A>G p.S126G | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1188904349, COSV100243673; called by muse, mutect2, varscan2
- VTCN1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV100062370; called by muse, mutect2, varscan2
- ZNF557 | c.1231T>C p.Y411H (on ENST00000414706 / NM_001044388.2; = p.Y418H on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99422824; called by muse, mutect2
- ZSCAN10 | c.508G>A p.G170S (on ENST00000252463; = p.G225S on NM_032805.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as COSV99374349; called by muse, mutect2, varscan2
- C1GALT1C1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2
- HMGCS1 | c.1005_1006dup p.L336Hfs*23 | Frame Shift Ins (INS) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- IGHD2-21 | c.5del p.I2Nfs*? | Frame Shift Del (DEL) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- KDM6A | c.2105dup p.H702Qfs*28 | Frame Shift Ins (INS) | VAF 46/94 reads (49%) | called by mutect2, pindel, varscan2
- MIPEP | c.1739C>A p.A580D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- MLLT6 | c.2975_3003del p.P992Hfs*82 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- SVIL | c.1606del p.E536Kfs*25 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by pindel, varscan2
- TTC16 | c.1528_1532del p.E510Qfs*15 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- VWA3A | c.1003del p.R335Gfs*49 | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | called by mutect2, pindel, varscan2
- ABCF1 | c.2505G>A p.L835= (on ENST00000326195 / NM_001025091.2; = p.L797= on NM_001090.3) | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs1021649525, COSV100401133; called by muse, mutect2, varscan2
- AEBP2 | c.825C>T p.S275= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99858090; called by muse, mutect2, varscan2
- AFMID | c.123C>A p.A41= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100015134; called by muse, mutect2, varscan2
- ARGFX | c.6G>A p.R2= | Silent (SNP) | VAF 10/238 reads (4%) | catalogued as COSV57682428; called by muse, mutect2
- CHD5 | c.867C>A p.S289= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99315373; called by muse, mutect2, varscan2
- CLTC | c.2619T>C p.P873= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV99293013; called by muse, mutect2, varscan2
- DAG1 | c.777C>G p.S259= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100445072, COSV100445246; called by muse, mutect2, varscan2
- EFTUD2 | c.927C>T p.F309= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as rs756409486, COSV101274562; called by muse, mutect2, varscan2
- EMID1 | c.726C>A p.T242= | Silent (SNP) | VAF 51/145 reads (35%) | catalogued as COSV100469366; called by muse, mutect2, varscan2
- FAT4 | c.10605T>C p.T3535= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100630456; called by muse, mutect2, varscan2
- GPR12 | c.15G>A p.L5= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101198032; called by muse, mutect2, varscan2
- HSF4 | c.207G>T p.A69= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV99263651; called by muse, mutect2, varscan2
- LRP2 | c.7680T>C p.Y2560= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99790595; called by muse, mutect2, varscan2
- MYH7 | c.2883G>T p.L961= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100806790; called by muse, mutect2, varscan2
- NFE2L1 | c.241C>A p.R81= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100671762; called by muse, mutect2, varscan2
- POU5F2 | c.318C>G p.A106= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101232958; called by muse, mutect2, varscan2
- RYR3 | c.3996C>T p.I1332= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV101214955; called by muse, mutect2, varscan2
- SLC2A9 | c.84G>A p.G28= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs978208661, COSV99305256; called by muse, mutect2
- STAT3 | c.1119G>A p.G373= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV99233344; called by muse, mutect2, varscan2
- TRIM33 | c.3015C>T p.T1005= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs376287925; called by muse, mutect2, varscan2
- TSC1 | c.1584C>T p.G528= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs149439187; ClinVar: likely benign / benign / not provided; called by muse, mutect2, varscan2
- TTN | c.50514A>T p.V16838= (on ENST00000591111; = p.V9414= on NM_003319.4) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100633815; called by muse, mutect2, varscan2
- C8orf86 | n.1078A>G | RNA (SNP) | VAF 26/89 reads (29%) | catalogued as rs1436997382, COSV100817600; called by muse, mutect2, varscan2
- CYHR1 | c.246+284G>A | Intron (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100024032; called by muse, mutect2, varscan2
